Gene-level copy-number profile of tumor specimen TCGA-C5-A1M5-01A from TCGA case TCGA-C5-A1M5, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 53.9 years (19,672 days).
Specimen TCGA-C5-A1M5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.62b86d57-e565-4621-b026-d1bd564aa38e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C5-A1M5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 826 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/03ba675f-395d-4a49-87d2-dd1e9b28d918

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 5; copy number 2: 3,924; copy number 3: 1,416; copy number 4: 50,732; copy number 5: 1,005; copy number 6: 1,045; copy number 7: 9; copy number 9: 893; copy number 10: 644; copy number 12: 103; copy number 15: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C5-A1M5-01A-11D-A13V-01): tumor purity 0.79, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:152,120,001–152,129,686, 2 genes: AC006017.1, YBX1P4.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,659 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,552,473–164,002,465, 850 genes, copy number 9 (within-gene range 9–19) (broad region; genes not listed).
- chr3:166,160,021–198,222,513, 628 genes, copy number 10 (broad region; genes not listed).
- chr8:113,376,669–113,493,281, 3 genes, copy number 10: AC107890.1, AC055788.2, AC055788.1.
- chr8:116,642,130–116,944,487, 6 genes, copy number 9: EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD.
- chr8:118,923,557–128,220,803, 163 genes, copy number 9–15 (broad region; genes not listed).
- chr8:134,477,788–134,713,049, 5 genes, copy number 9 (within-gene range 6–9): ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3.
- chr8:138,588,235–139,127,953, 4 genes, copy number 9: COL22A1, AC027541.1, AC100807.1, AC100807.2.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
